Somatic mutation profile of tumor specimen TCGA-AG-3594-01A (aliquot TCGA-AG-3594-01A-02D-1989-10) from TCGA case TCGA-AG-3594, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.4 years (28,277 days).
Specimen TCGA-AG-3594-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de899de5-7a94-4842-92ce-c0210a923689.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3594-10A (Blood Derived Normal), aliquot TCGA-AG-3594-10A-01W-1990-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fe656f1-3993-41c1-994a-e6f2e9d67de2

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 9, Silent 5, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHST2 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1309715355, COSV58887080; called by muse, mutect2, varscan2
- GTPBP3 | c.1280del p.P427Rfs*3 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as COSV100258720; called by mutect2, varscan2
- HID1 | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100172785; called by muse, mutect2, varscan2
- IMP3 | c.521A>G p.N174S | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs200453864, COSV100145772; called by muse, mutect2, varscan2
- JPH3 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs376022547; called by muse, varscan2
- MED12 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.394); catalogued as rs1339711860, COSV100377508; called by muse, mutect2, varscan2
- PCDHA8 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs1554139301, COSV65335257; called by muse, mutect2, varscan2
- SIGLEC6 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as rs780557269, COSV58431654; called by muse, mutect2, varscan2
- SLC4A3 | c.2033C>T p.T678M | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759168094, COSV99812279; called by muse, mutect2, varscan2
- ZNF423 | c.2834G>A p.R945Q (on ENST00000563137 / NM_001379286.1; = p.R937Q on NM_015069.4) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.168); catalogued as COSV52205964; called by muse, mutect2, varscan2
- PLK1 | c.1425+4_1425+7del p.X475_splice | Splice Site (DEL) | VAF 36/148 reads (24%) | called by mutect2, pindel
- COL7A1 | c.5964C>T p.G1988= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs774695454, COSV100095921, COSV60394615; called by muse, varscan2
- GATA3 | c.444G>A p.P148= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs758531534, COSV60515067; called by muse, mutect2, varscan2
- HYDIN | c.7863G>A p.P2621= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs573398504, COSV99992599; called by mutect2, varscan2
- PIK3CD | c.897G>A p.P299= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as rs149279787; called by muse, varscan2
- SPTA1 | c.4068C>A p.I1356= | Silent (SNP) | VAF 43/139 reads (31%) | catalogued as COSV100934109, COSV100934758, COSV63749559; called by mutect2, varscan2
